CCDI case PBBJRI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e2634ec5-27df-4824-b137-63250ff0354d

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Large cell medulloblastoma: ICD-O-3 morphology code: 9474/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.9 years (5,072 days).

Biospecimens (3 samples)
- Sample 0DA692: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DA694: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DA695: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
